Gene-level copy-number profile of specimen HCM-SANG-1310-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-1310-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-1310-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cfab54bb-3c5e-4770-a677-1a63813f593b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1310-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,736 have no estimate.
https://portal.gdc.cancer.gov/files/9c20b0fc-bd12-482b-9029-c08ddd050948

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,464; copy number 2: 24,991; copy number 3: 18,655; copy number 4: 7,836; copy number 5: 2,622; copy number 6: 1,306; copy number 7: 13.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,888 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:113,856,635–113,901,237, 2 genes, copy number 5 (within-gene range 4–5): AP4B1-AS1, BCL2L15.
- chr5:58,198–45,895,970, 679 genes, copy number 5–7 (broad region; genes not listed).
- chr6:42,696,598–55,681,021, 249 genes, copy number 5–7 (broad region; genes not listed).
- chr6:93,811,825–170,738,536, 1,094 genes, copy number 5–7 (broad region; genes not listed).
- chr8:111,376,639–145,066,685, 509 genes, copy number 5 (broad region; genes not listed).
- chr9:41,890,314–42,714,539, 21 genes, copy number 6: CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1.
- chr10:49,818,279–50,965,220, 32 genes, copy number 5: PARG, RPL35AP24, TIMM23B, TIMM23B-AGAP6, SNORA74C-2, RNA5SP317, AL442003.1, AGAP6, FAM21EP, SLC9A3P3, WASHC2A, SLC9A3P1, ASAH2, DYNC1I2P1, SGMS1, AC069547.2, AC069547.1, AL117341.1, RNU7-107P, SGMS1-AS1, SHQ1P1, BEND3P1, NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1, AL589794.2, ASAH2B, A1CF, AL512366.1, CCDC58P2, AL731537.2.
- chr10:58,512,872–59,247,774, 7 genes, copy number 5–6 (within-gene range 3–6): BICC1, FAM133CP, RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL.
- chr10:61,662,929–64,693,446, 30 genes, copy number 5 (within-gene range 3–5): CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1, AC013287.1.
- chr10:69,510,166–69,779,838, 12 genes, copy number 5: AC016821.1, TMEM256P1, NEUROG3, AL450311.1, MTATP6P23, MTCO2P23, MTCO1P23, MTND2P15, MTND1P20, FAM241B, LINC02651, RPL5P26.
- chr10:70,672,506–73,520,070, 76 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr10:79,544,087–80,778,088, 54 genes, copy number 5: RPS12P18, SFTPA2, MBL3P, SFTPA3P, SFTPA1, LINC02679, AL132656.2, NUTM2B-AS1, AL132656.3, AL132656.4, BEND3P3, AL132656.1, NUTM2B, AL135925.1, NUTM2E, NPAP1P2, CTSLP6, PGGT1BP2, AL512662.1, BMS1P21, MBL1P, SFTPD, SFTPD-AS1, ZNRF2P3, DPY19L2P5, AL356095.1, C1DP3, C1DP2, C1DP4, TMEM254-AS1, AL356095.3, TMEM254, AL356095.2, RPL22P18, PLAC9, ANXA11, LINC00857, RPS12P2, AL513174.1, EIF5AP4, AL359195.2, MAT1A, ZNF519P1, AL359195.1, DYDC1, DYDC2, PRXL2A, TSPAN14, AC021028.1, SH2D4B, LINC02655, RPS7P9, AC027673.1, FARSBP1.
- chr10:83,672,406–84,561,263, 19 genes, copy number 5: LINC02650, AC069540.1, RNU6-129P, AL390786.1, RNU1-65P, HMGN2P8, AL603756.1, GHITM, C10orf99, CDHR1, LRIT2, RGR, LRIT1, LINC00858, CCSER2, RPL12P29, TNPO1P1, CACYBPP1, RPS3AP5.
- chr10:103,479,603–104,624,795, 28 genes, copy number 5: NEURL1-AS1, NEURL1, AL121929.1, AL121929.3, SH3PXD2A, AL121929.2, Y_RNA, SH3PXD2A-AS1, AL133355.1, STN1, SLK, RN7SL524P, COL17A1, MIR936, SFR1, CFAP43, MIR609, GSTO1, MIR4482, GSTO2, ITPRIP, AL162742.1, AL162742.2, ITPRIP-AS1, CFAP58-DT, CFAP58, LINC02620, AL161646.1.
- chr10:109,528,119–109,681,041, 4 genes, copy number 5: PHB2P1, BTF3P15, AL390123.1, XIAPP1.
- chr10:112,823,490–112,832,454, 2 genes, copy number 5: AL158212.3, AL158212.4.
- chr10:117,128,521–119,997,709, 57 genes, copy number 6: VAX1, MIR3663HG, MIR3663, RPL12P26, KCNK18, AL731557.1, SLC18A2, AL391988.1, PDZD8, AC005871.2, EMX2OS, EMX2, AC005871.1, LINC02674, AL513324.1, RAB11FIP2, AC022395.1, CASC2, AL354863.1, FAM204A, LINC00867, SLC25A18P1, PRLHR, TOMM22P5, CACUL1, AL139407.1, AL157388.1, RPL17P36, LDHAP5, NANOS1, EIF3A, SNORA19, AL355598.1, AL355598.2, DENND10, SFXN4, PRDX3, GRK5, GRK5-IT1, RN7SL749P, AL583824.1, MIR4681, RGS10, AC012468.1, TIAL1, RAD1P1, RPS8P4, BAG3, TXNP1, INPP5F, RN7SL846P, PHACTR2P1, AL133461.1, MCMBP, SEC23IP, MIR4682, NACAP2.
- chr10:127,907,103–128,960,062, 9 genes, copy number 6: PTPRE, AL158166.2, AL158166.1, AL390236.1, MKI67, LINC01163, AL390763.1, LINC02667, AL355537.1.
- chr12:118,981,541–119,163,051, 2 genes, copy number 5 (within-gene range 4–5): SRRM4, AC087885.1.
- chr12:119,031,039–123,708,399, 173 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr12:126,165,730–126,191,406, 1 gene, copy number 5 (within-gene range 4–5): AC005888.1.
- chr13:39,209,116–39,791,665, 4 genes, copy number 6 (within-gene range 4–6): LHFPL6, COG6, MIR4305, RNY4P14.
- chr20:31,847,637–64,327,972, 824 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,467. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
